Somatic mutation profile of tumor specimen TCGA-TQ-A7RI-01A (aliquot TCGA-TQ-A7RI-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RI, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 37.8 years (13,799 days).
Specimen TCGA-TQ-A7RI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 811df05f-3123-451d-a312-c79fd0f9910d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RI-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RI-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2d41f9c-decf-4936-b938-146ac93115d1

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Frame Shift Del 3, Nonsense Mutation 2, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 73/202 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP11C | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100558136; called by muse, mutect2, varscan2
- C5orf49 | c.237A>C p.K79N | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV101296858; called by muse, mutect2, varscan2
- CD163L1 | c.2556A>C p.K852N | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV100550210; called by muse, mutect2, varscan2
- CETN2 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV100938665; called by muse, mutect2, varscan2
- CIC | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | catalogued as COSV99359081; called by muse, mutect2
- DAPK1 | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 25/333 reads (8%) | catalogued as COSV100800726; called by muse, mutect2
- DRC7 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.168); catalogued as rs141535311, COSV100395678; called by muse, mutect2, varscan2
- HSPA9 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1451402921, COSV99785545; called by muse, mutect2
- IPO4 | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99938111; called by muse, mutect2, varscan2
- LGALS1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs765635524, COSV99313784; called by muse, mutect2, varscan2
- MADD | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV100211578; called by muse, mutect2
- MMP28 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1299556556; called by muse, mutect2
- OR2T2 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737700; called by muse, mutect2, varscan2
- PXDNL | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV62478535; called by muse, mutect2
- STAP1 | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99609515; called by muse, mutect2
- TMTC1 | c.1033C>A p.L345M (on ENST00000539277 / NM_001193451.2; = p.L237M on NM_175861.3) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99759989; called by muse, mutect2, varscan2
- TMTC4 | c.599C>T p.A200V (on ENST00000376234 / NM_001350577.2; = p.A219V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs777688094, COSV60891276; called by muse, mutect2, varscan2
- ZNF184 | c.773C>G p.A258G | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV99279746; called by muse, mutect2, varscan2
- ZNF74 | c.1714A>G p.T572A | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs763422465, COSV100677503; called by muse, mutect2, varscan2
- CIC | c.102_103del p.F35Pfs*15 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by pindel, varscan2
- RRAGD | c.248_249del p.F83Sfs*15 | Frame Shift Del (DEL) | VAF 185/611 reads (30%) | called by mutect2, pindel, varscan2
- ZNF214 | c.28_29del p.I10Yfs*37 | Frame Shift Del (DEL) | VAF 54/182 reads (30%) | called by mutect2, pindel, varscan2
- UTP14A | c.222C>T p.F74= | Silent (SNP) | VAF 28/645 reads (4%) | catalogued as COSV100928977; called by muse, mutect2
- XIST | n.11318_11320del | RNA (DEL) | VAF 13/78 reads (17%) | catalogued as rs1209184077; called by pindel, varscan2
